Somatic mutation profile of tumor specimen TCGA-A7-A6VW-01A (aliquot TCGA-A7-A6VW-01A-21D-A33E-09) from TCGA case TCGA-A7-A6VW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.0 years (17,539 days).
Specimen TCGA-A7-A6VW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33eb7fe9-af62-454a-9ab0-82a563cb0877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A6VW-10A (Blood Derived Normal), aliquot TCGA-A7-A6VW-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33bca569-cc72-45fc-9f40-85452841a12c

The open-access MAF lists 68 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Nonsense Mutation 4, Frame Shift Del 2, Translation Start Site 1, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.2709del p.C903Wfs*97 | Frame Shift Del (DEL) | VAF 11/18 reads (61%) | catalogued as rs80357594; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FAH | c.1063-2A>G p.X355_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as rs1555442385, COSV99930461; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 17/22 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV99484109; called by muse, mutect2, varscan2
- ANKS6 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs761831193, COSV100782368; called by muse, mutect2, varscan2
- ARID1B | c.5292G>C p.K1764N | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs774161575, COSV99271072; called by muse, mutect2, varscan2
- ASB15 | c.469T>C p.Y157H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV99306873; called by muse, mutect2, varscan2
- ATP1A2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100768079; called by muse, mutect2, varscan2
- BTBD1 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99915641; called by muse, mutect2, varscan2
- CASP3 | c.576C>A p.D192E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100395047; called by muse, mutect2
- CCDC30 | c.1912T>C p.Y638H (on ENST00000340612; = p.Y595H on NM_001080850.3) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100501567; called by muse, mutect2
- COMMD4 | c.196A>G p.K66E | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV99143143; called by muse, mutect2, varscan2
- CRACD | c.2156T>A p.F719Y | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99949807; called by muse, mutect2, varscan2
- DACH2 | c.265A>C p.I89L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.634); catalogued as COSV100913713; called by muse, mutect2, varscan2
- DHTKD1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1413322402, COSV99536790; called by muse, mutect2, varscan2
- DMGDH | c.1615A>C p.K539Q | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99669363; called by muse, mutect2, varscan2
- DNAJB9 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99974566; called by muse, mutect2, varscan2
- EPG5 | c.5747T>A p.L1916* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV99957833; called by muse, mutect2, varscan2
- FBXW7 | c.1625A>T p.N542I (on ENST00000281708 / NM_001349798.2; = p.N462I on NM_018315.5) | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55966512; called by muse, mutect2, varscan2
- GALNTL5 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as rs377355982; called by muse, mutect2, varscan2
- GUCY1A2 | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99976151; called by muse, mutect2, varscan2
- HDAC6 | c.3579G>C p.Q1193H | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100491160; called by muse, mutect2, varscan2
- HNRNPU | c.2200C>A p.P734T (on ENST00000283179; = p.P796T on NM_004501.3) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99310576; called by muse, mutect2
- IGF2BP3 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV51688864; called by muse, mutect2, varscan2
- INTS12 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.401); catalogued as rs1466709231, COSV100415763; called by muse, mutect2, varscan2
- LRIF1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV63896890, COSV63897061; called by muse, mutect2, varscan2
- LRP2 | c.5339G>A p.G1780D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1470459851, COSV55570318; called by muse, mutect2
- MED12L | c.2728G>T p.G910C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV99854228; called by muse, mutect2, varscan2
- NPC1L1 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs372455452; called by muse, mutect2, varscan2
- OBSCN | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.825); catalogued as COSV52790504, COSV99482576; called by muse, mutect2, varscan2
- OR51V1 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1296789492, COSV100343462; called by muse, mutect2, varscan2
- ORC1 | c.2217G>T p.K739N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV100856729; called by muse, mutect2, varscan2
- PAPPA2 | c.3505C>A p.P1169T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs199857969, COSV100868444; called by muse, mutect2, varscan2
- PCYOX1L | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as COSV99199253; called by muse, mutect2, varscan2
- PHLDA3 | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100943642; called by muse, mutect2, varscan2
- PLCB2 | c.1700A>G p.K567R | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.91); PolyPhen benign (0.05); catalogued as COSV99542452; called by muse, mutect2, varscan2
- PLOD3 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99778194; called by muse, mutect2, varscan2
- RMDN1 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99547937; called by muse, mutect2, varscan2
- SEMA5B | c.2696A>G p.Y899C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99532844; called by muse, mutect2, varscan2
- SOX4 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs777539753, COSV99782134; called by muse, mutect2, varscan2
- SYT10 | c.1117T>G p.Y373D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951822; called by muse, mutect2, varscan2
- TADA3 | c.546T>A p.D182E | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.43); PolyPhen benign (0.089); catalogued as COSV99809596; called by muse, mutect2, varscan2
- TBC1D17 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV55577350; called by muse, mutect2, varscan2
- TCP1 | c.1640A>G p.D547G | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1343456367, COSV100365018; called by muse, mutect2, varscan2
- TMEM63A | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs779164268, COSV100834433; called by muse, varscan2
- TRAFD1 | c.949G>C p.A317P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99986955; called by muse, mutect2
- TUBB8 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV100226138; called by muse, mutect2, varscan2
- VPS33A | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV99931493; called by muse, mutect2, varscan2
- ZMYM5 | c.1913T>G p.L638* | Nonsense Mutation (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100562810; called by muse, mutect2, varscan2
- ZNF770 | c.73A>T p.R25W | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99063381; called by muse, mutect2, varscan2
- ATP2B2 | c.3344del p.G1115Afs*9 (on ENST00000352432; = p.G1081Afs*9 on NM_001683.5) | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- GAB4 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- RBP2 | c.276_278del p.V93del | In Frame Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- ARHGAP22 | c.552G>A p.R184= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV99985772; called by muse, mutect2
- CD1D | c.873C>T p.I291= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV63808977; called by muse, mutect2, varscan2
- COL27A1 | c.5121G>T p.V1707= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV100621220; called by muse, mutect2, varscan2
- COL4A2 | c.2184A>G p.E728= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100847443; called by muse, mutect2, varscan2
- DMXL1 | c.5685T>C p.S1895= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100224600; called by muse, mutect2, varscan2
- HDAC9 | c.2124C>T p.D708= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs764822105, COSV101286927; called by muse, mutect2, varscan2
- INTS7 | c.579G>A p.L193= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100877545; called by muse, mutect2, varscan2
- LRP10 | c.1005A>G p.A335= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100612456; called by muse, mutect2, varscan2
- PLCB2 | c.1197C>A p.S399= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV99542453; called by muse, mutect2, varscan2
- POLA2 | c.1068G>A p.T356= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs747786814, COSV99640609; called by muse, mutect2, varscan2
- SHF | c.171C>T p.C57= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99334691; called by muse, mutect2, varscan2
- SLC6A20 | c.1452C>T p.Y484= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs768529237, COSV100653891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM9 | c.342A>T p.S114= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100031976; called by muse, mutect2, varscan2
- WNT7A | c.699C>T p.N233= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs760426340, COSV53199464; called by muse, mutect2, varscan2
- RYR2 | c.11145+1263C>G | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100768851; called by muse, mutect2
